Gene-level copy-number profile of tumor specimen TCGA-EJ-7784-01A from TCGA case TCGA-EJ-7784, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,183 days).
Specimen TCGA-EJ-7784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.fd5998ec-9011-42b6-9d31-37df1ef49374.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7784-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f1a13bae-920f-48ce-91d0-43321c0ecf7c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 12; copy number 2: 3,919; copy number 3: 858; copy number 4: 40,861; copy number 5: 7,866; copy number 6: 3,238; copy number 7: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7784-01A-11D-2112-01): tumor purity 0.69, ploidy 4.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:110,069,961–111,699,033, 45 genes: MIR4267, MALL, MIR4436B1, NPHP1, ACTR1AP1, MTLN, AC140479.3, AC140479.4, MALLP1, MIR4436B2, AC140479.5, AC140479.1, AC140479.2, LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1, ACOXL, RPL5P9, MIR4435-2HG, ACOXL-AS1, BCL2L11, AC108463.2, AC108463.1, AC108463.3, AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2, AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1.
- chr2:111,675,026–111,675,343, 1 gene: RPL34P8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
